Somatic mutation profile of tumor specimen MMRF_1613_1_BM_CD138pos (aliquot MMRF_1613_1_BM_CD138pos_T1_KHS5U_K14086) from MMRF case MMRF_1613, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.3 years (27,126 days).
Specimen MMRF_1613_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cabd584f-4bda-4c36-a895-b3c234599718.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1613_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1613_1_PB_Whole_C1_KHS5U_K14076; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb0a0f60-76a3-4856-a5b8-e4cc220ea024

The open-access MAF lists 98 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 26, Silent 16, Intron 11, 5'UTR 3, RNA 3, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.7429T>C p.F2477L | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs782141890; called by muse, mutect2, varscan2
- CLIC5 | c.1189G>A p.E397K (on ENST00000185206 / NM_001370649.1; = p.E238K on NM_016929.5) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs368704000; called by muse, mutect2, varscan2
- CMTM8 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV56780431; called by muse, mutect2, varscan2
- IGHV2-70 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs557763852; called by muse, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, varscan2
- IGHV2-70 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as rs375927713; called by muse, varscan2
- KDM5C | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64767235; called by muse, mutect2, varscan2
- LTB | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 224/477 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs571318566, COSV53001827, COSV53002251; called by muse, varscan2
- MRPS27 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759474723; called by muse, mutect2, varscan2
- PLA2G4F | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.95); catalogued as rs375597223; called by muse, mutect2, varscan2
- RRP9 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1254870023, COSV51754417; called by muse, mutect2, varscan2
- SDK2 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs200893218, COSV66181001; called by muse, mutect2, varscan2
- SORCS2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749759274, COSV100213130; called by muse, mutect2, varscan2
- SUPT6H | c.4979G>A p.R1660Q | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs148310656; called by muse, mutect2, varscan2
- UTY | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58872815; called by muse, mutect2, varscan2
- CCPG1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 207/331 reads (63%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CEPT1 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE3 | c.649T>G p.Y217D | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DSP | c.3422A>C p.Q1141P | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- FRRS1L | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF10 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- GPR179 | c.6485G>T p.G2162V (on ENST00000621958; = p.G2161V on NM_001004334.4) | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- IZUMO2 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 306/659 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLC2 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRT9 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- MYH13 | c.4752T>G p.D1584E | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MYOM1 | c.3112G>T p.V1038F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, varscan2
- OTOG | c.8030G>A p.C2677Y | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAN3 | c.2477G>T p.G826V | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDZD2 | c.7291C>A p.P2431T | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2
- RANBP17 | c.1322A>G p.Q441R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RBM44 | c.646C>T p.H216Y (on ENST00000611254; = p.H850Y on NM_001080504.2) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- SELP | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 24/944 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A20 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 134/202 reads (66%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.55_56del p.K19Efs*22 | Frame Shift Del (DEL) | VAF 108/235 reads (46%) | called by mutect2, pindel, varscan2
- SLX4IP | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- THUMPD1 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.6353G>A p.G2118E | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ALLC | c.1065C>T p.D355= | Silent (SNP) | VAF 118/234 reads (50%) | catalogued as rs1479932817, COSV52993134; called by muse, mutect2, varscan2
- CYP4A22 | c.462C>T p.I154= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV99594712; called by muse, mutect2
- GPD2 | c.1455G>A p.Q485= | Silent (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- H3-5 | c.144T>A p.L48= | Silent (SNP) | VAF 169/338 reads (50%) | called by muse, mutect2, varscan2
- IGLL5 | c.129T>C p.V43= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1162059724; called by muse, varscan2
- KCNK2 | c.336G>A p.T112= (on ENST00000444842 / NM_001017425.3; = p.T97= on NM_014217.4) | Silent (SNP) | VAF 80/295 reads (27%) | catalogued as rs773167171, COSV67204559; called by muse, mutect2, varscan2
- KCNV2 | c.1572C>A p.A524= | Silent (SNP) | VAF 147/309 reads (48%) | called by muse, mutect2, varscan2
- LHX4 | c.528C>T p.Y176= | Silent (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- LILRA1 | c.1416G>T p.L472= | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, varscan2
- MTCL1 | c.4251C>T p.T1417= (on ENST00000306329 / NM_001378206.1; = p.T1098= on NM_015210.4) | Silent (SNP) | VAF 6/154 reads (4%) | called by muse, mutect2
- PARD3B | c.408G>A p.L136= | Silent (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- PPP1R13L | c.468G>T p.A156= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- TFIP11 | c.1341T>C p.Y447= | Silent (SNP) | VAF 66/116 reads (57%) | catalogued as rs570811760; called by muse, mutect2, varscan2
- TLDC2 | c.219C>T p.T73= | Silent (SNP) | VAF 136/288 reads (47%) | catalogued as rs760164325, COSV54113669, COSV54114900; called by muse, mutect2, varscan2
- TLN2 | c.1563G>A p.S521= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs146430103, COSV60889952; called by muse, mutect2, varscan2
- TTC6 | c.588G>A p.G196= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- AC008740.1 | n.130G>A | RNA (SNP) | VAF 20/51 reads (39%) | catalogued as rs1305602650; called by muse, mutect2, varscan2
- ADAMTS18 | c.*1105A>C | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- AL035461.3 | c.*131dup | 3'UTR (INS) | VAF 24/265 reads (9%) | called by mutect2, pindel
- ATXN7L3 | c.665+111C>T | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- BLOC1S1 | c.352-133G>A | Intron (SNP) | VAF 254/533 reads (48%) | catalogued as rs1012552963; called by muse, mutect2, varscan2
- C12orf4 | c.*1965G>A | 3'UTR (SNP) | VAF 50/92 reads (54%) | catalogued as rs1482932346; called by muse, mutect2, varscan2
- CCDC6 | c.-46G>A | 5'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs1161769114; called by muse, mutect2
- CNOT2 | c.1392-385G>A | Intron (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- DCAF12 | c.-70A>G | 5'UTR (SNP) | VAF 31/53 reads (58%) | called by muse, mutect2, varscan2
- DICER1 | c.*3881C>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.*326T>G | 3'UTR (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- EPN2 | c.*866C>T | 3'UTR (SNP) | VAF 54/207 reads (26%) | called by muse, mutect2, varscan2
- FAT3 | c.*4332A>G | 3'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- FLOT1 | c.211-10C>T | Intron (SNP) | VAF 54/103 reads (52%) | called by muse, mutect2, varscan2
- FOXP1 | c.*2821_*2822insG | 3'UTR (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- GGCTP1 | n.417T>G | RNA (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2, varscan2
- IKZF3 | c.*7854C>G | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- ITGB6 | c.*460del | 3'UTR (DEL) | VAF 28/56 reads (50%) | called by mutect2, varscan2
- JAG1 | c.*1078G>A | 3'UTR (SNP) | VAF 42/77 reads (55%) | catalogued as rs1228478173; called by muse, mutect2, varscan2
- KLF8 | c.647-621G>A | Intron (SNP) | VAF 17/17 reads (100%) | called by muse, mutect2
- KLHL6 | c.*2271_*2272del | 3'UTR (DEL) | VAF 48/82 reads (59%) | called by mutect2, pindel, varscan2
- LCN15 | chr9:136764562 C>A | 5'Flank (SNP) | VAF 19/31 reads (61%) | catalogued as rs1310172728; called by muse, mutect2, varscan2
- LONRF2 | c.*8098G>A | 3'UTR (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- LTB | c.209-79C>T | Intron (SNP) | VAF 50/104 reads (48%) | catalogued as rs571115871; called by muse, varscan2
- LTB | c.163-141G>A | Intron (SNP) | VAF 135/290 reads (47%) | catalogued as rs4647180; called by muse, mutect2, varscan2
- MAP1B | c.*1583T>C | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- MAP1B | c.*3826A>G | 3'UTR (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- MPZL1 | c.*500G>A | 3'UTR (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- NFASC | c.*2764G>C | 3'UTR (SNP) | VAF 98/275 reads (36%) | called by muse, mutect2, varscan2
- NR2F1 | c.-104C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+2302T>A | Intron (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- PAK2 | c.*1764A>C | 3'UTR (SNP) | VAF 137/391 reads (35%) | called by muse, mutect2, varscan2
- PPP1R12B | c.2863-5441T>C | Intron (SNP) | VAF 135/403 reads (33%) | called by muse, mutect2, varscan2
- PSMB4 | c.693+92G>A | Intron (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- RARRES2P6 | n.328G>A | RNA (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- SFT2D2 | c.*4794C>G | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SGCB | c.*2294del | 3'UTR (DEL) | VAF 12/34 reads (35%) | catalogued as rs1560564976; called by mutect2, pindel
- SGPL1 | c.*2915G>A | 3'UTR (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2
- SRD5A3 | c.*1301T>C | 3'UTR (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+99G>C | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- TMEM213 | c.*1873del | 3'UTR (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- UACA | c.*1003G>A | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- UNC5D | c.*1944T>G | 3'UTR (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- ZCRB1 | c.*284G>A | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
